Gene-level copy-number profile of tumor specimen TCGA-N5-A4RJ-01A from TCGA case TCGA-N5-A4RJ, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Age at diagnosis: 61.2 years (22,341 days).
Specimen TCGA-N5-A4RJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.a1cf5944-b8fd-4d1d-8d42-902740030d91.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce20d8ba-ce4d-4073-a654-397ce77d1ad7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,101; copy number 2: 14,902; copy number 3: 27,413; copy number 4: 14,680; copy number 5: 510; copy number 6: 877; copy number 7: 10; copy number 8: 140; copy number 10: 18; copy number 11: 80; copy number 13: 21; copy number 15: 34; copy number 16: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RJ-01A-11D-A28Q-01): tumor purity 0.86, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,547,184–15,280,873, 8 genes: RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 310 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:96,841,995–98,930,637, 18 genes, copy number 10 (within-gene range 2–10): AC096585.1, COX7A2P2, AC108515.1, STPG2, AC034154.1, STPG2-AS1, CRYZP2, RPL5P12, DUTP8, AC019077.1, RAP1GDS1, AC058823.1, TSPAN5, AC108159.1, AC114811.2, AC114811.1, BTF3P13, EIF4E.
- chr4:130,963,925–131,975,952, 11 genes, copy number 8: AC093902.1, AC025554.1, RNU6-224P, LINC02377, AC105424.1, RN7SL205P, SNHG27, SNORA70, AC107393.1, RPL7AP28, AC096711.2.
- chr4:139,495,941–139,623,232, 5 genes, copy number 13 (within-gene range 2–13): SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1.
- chr8:35,672,195–36,321,404, 10 genes, copy number 7: AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr10:59,551,404–62,096,944, 23 genes, copy number 13–16 (within-gene range 5–16): MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B.
- chr10:74,821,610–76,560,994, 34 genes, copy number 15: AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1.
- chr10:77,313,941–80,289,658, 80 genes, copy number 11 (broad region; genes not listed).
- chr16:7,004,007–7,726,951, 6 genes, copy number 8: RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1.
- chr22:21,759,657–22,881,396, 123 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 996. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
